Surgical pathology report (de-identified scan), TCGA case TCGA-MP-A4TI, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Washington University - Mayo Clinic, specimen TCGA-MP-A4TI-01A (Primary Tumor).

[page 1 of 3]
Surgical Pathology
REVISED REPORT (Revised information underlined)
Addendum/Procedure included
Requested By:

ICD-0-3
adenocarcinoma, NOS 8140/3
Site: Lung (R) Lower lobe C34.3

SLIDE DISPOSITION:

DIAGNOSIS:

A. Lung, right lower lobe, wedge resection: Invasive grade 4 (of 4) adenocarcinoma, forming a well-circumscribed, necrotic 4.0 x 2.2 x 2.0 cm mass. Visceral pleural involvement and angiolymphatic invasion are absent. The surgical margin is negative for tumor.

B. Lymph nodes, station 4R, biopsy: Multiple (6) fragments of lymph nodes are negative for tumor.

C. Lymph nodes, station 9R set #1, biopsy: A single (1) lymph node is negative for tumor.

D. Lymph nodes, station 7 set #1, biopsy: Multiple (10) fragments of lymph nodes are negative for tumor. One lymph node contains a necrotizing granuloma (not present at the time of frozen section).
Special stains results will be issued as an addendum.

E. Lymph nodes, bronchus intermedius, biopsy: Metastatic adenocarcinoma is identified in a single (1 of 1) lymph node.

F. Lymph nodes, anterior mediastinal, biopsy: Multiple (2) fragments of lymph nodes are negative for tumor.

G. Lymph nodes, station 7 set #2, biopsy: A single (1) lymph node is negative for tumor.

H. Lymph nodes, station 9R set #2, biopsy: A single (1) lymph node is negative for tumor.

I. Lung, right lower lobe, completion lobectomy: No residual tumor identified. A matted mass of intrapulmonary peribronchial lymph nodes is metastatically involved.

[with available surgical material, AJCCpT2a1 7th edition,

This final pathology report is based on the gross/macrosopic examination and frozen section histologic evaluation of the specimen(s). Hematoxylin and Eosin (H&E) permanent sections are reviewed to confirm these findings. Any substantive changes identified on permanent section review will be reflected in a revised report.

ADDENDUM:

The GMS and acid fast stains are negative for organisms.

Transcribed by:

Signed by

ADDENDUM:

At the request of _____, k-ras mutation analysis will be performed on paraffin-embedded tissue (block E1). Upon completion, results will be available in _____

hw
10/29/12

[page 2 of 3]
Also at the request of _____, EGFR mutation analysis genotyping will performed by Genzyme Genetics on paraffin embedded tissue (block E1). Upon completion, results will be available in _____

Transcribed by:

Signed by

AMENDMENTS: (Previous Signout Date:

Revision Description: Granuloma identified on permanent sections not present at time of frozen section.

....Original Diagnosis....

A. Lung, right lower lobe, wedge resection: Invasive grade 4 (of 4) adenocarcinoma, forming a well-circumscribed, necrotic 4.0 x 2.2 x 2.0 cm mass. Visceral pleural involvement and angiolymphatic invasion are absent. The surgical margin is negative for tumor.

B. Lymph nodes, station 4R, biopsy: Multiple (6) fragments of lymph nodes are negative for tumor.

C. Lymph nodes, station 9R set #1, biopsy: A single (1) lymph node is negative for tumor.

D. Lymph nodes, station 7 set #1, biopsy: Multiple (10) fragments of lymph nodes are negative for tumor.

E. Lymph nodes, bronchus intermedius, biopsy: Metastatic adenocarcinoma is identified in a single (1 of 1) lymph node.

F. Lymph nodes, anterior mediastinal, biopsy: Multiple (2) fragments of lymph nodes are negative for tumor.

G. Lymph nodes, station 7 set #2, biopsy: A single (1) lymph node is negative for tumor.

H. Lymph nodes, station 9R set #2, biopsy: A single (1) lymph node is negative for tumor.

I. Lung, right lower lobe, completion lobectomy: No residual tumor identified. A matted mass of intrapulmonary peribronchial lymph nodes is metastatically involved.

[With available surgical material, AJCCpT2aN1 7th edition,

This final pathology report is based on the gross/macrosopic examination and frozen section histologic evaluation of the specimen(s). Hematoxylin and Eosin (H&E) permanent sections are reviewed to confirm these findings. Any substantive changes identified on permanent section review will be reflected in a revised report.

GROSS DESCRIPTION:

A. Received fresh labeled "wedge excision right lower lobe of lung" is an 11.2 x 5.0 x 4.0 cm lung wedge resection. There is a 4.0 x 2.2 x 2.0 cm ill, solid mass located 0.4 cm from the stapled margin. The mass umbilicates the visceral pleura which is inked and submitted perpendicularly. Representative sections are submitted. Grossed by _____

B. Received fresh labeled "station 4 right lymph nodes" is a 3.8 x 3.2 x 1.4 cm aggregate of lymphatic tissue and fat. Lymphatic tissue is entirely submitted. Grossed by _____

C. Received fresh labeled "station 9 right lymph nodes" is a 1.1 x 0.5 x 0.2 cm aggregate of lymphatic tissue which is all submitted.

[page 3 of 3]
Grossed by

D. Received fresh labeled "station #7 lymph nodes" is a 3.6 x 3.1 x 0.9 cm aggregate of lymphatic tissue which is all submitted.
Grossed by

E. Received fresh labeled "bronchus intermedius lymph node" is a 1.5 x 0.8 x 0.8 cm aggregate of lymphatic tissue which is all submitted.
Grossed by

F. Received fresh labeled "anterior mediastinal lymph node" is a 1.5 x 1.0 x 0.4 cm aggregate of lymphatic tissue which is all submitted.
Grossed by

G. Received fresh labeled "station #7 set 2" is a 2.3 x 0.8 x 0.8 cm aggregate of lymphatic tissue which is all submitted. Grossed by

H. Received fresh labeled "station 9 right lymph node - set 2" is a 1.7 x 1.2 x 0.3 cm aggregate of lymphatic tissue which is all submitted. Grossed by

I. Received fresh labeled "right lung" is a 470.0 gram completion lobectomy. No masses are identified. Representative sections are submitted. Grossed by

BLOCK SUMMARY:

Part A: wedge excision right lower lobe lung

- 1 Rt lower lung mass 1
- 2 Rt lower lung mass 2
- 3 Rt lower lung mass 3

Part B: Right station 4 lower paratracheal lymph nodes

- 1 Rt lower paratrach LN(B1)
- 2 Rt lower paratrach LN(B2)
- 3 Rt lower paratrach LN(B3)
- 4 Rt lower paratrach LN(B4)

Part C: Right station 9 pulmonary ligament

- 1 Rt pulmonary ligament LN(C1)

Part D: Station 7 subcarinal lymph nodes

- 1 Subcarinal LN(D1)
- 2 Subcarinal LN(D2)
- 3 Subcarinal LN(D3)
- 4 Subcarinal LN(D4)

Part E: Bronchus intermedius lymph node

- 1 Bronchus intermedius LN(E1)

Part F: Anterior mediastinal lymph node

- 1 Ant mediastinal LNs 2 (F1)
- 2 Ant mediastinal LN 1 (F2)

Part G: station 7 subcarinal lymph node #2

- 1 Subcarinal LN set 2

Part H: station 9 right pulmonary ligament lymph node #2

- 1 Rt pulmonary ligament LN

Part I: Right Lung

- 1 Bronch margin
- 2 Bronch margin
- 3 Peribronchial LN
- 4 Peribronchial LN
- 5 Rt lung normal

Source: NCI Genomic Data Commons file 731e6765-bafe-4fb7-b685-32aefaa9cf21 (TCGA-MP-A4TI.FE74F98E-3131-4F7F-9899-AF5259B3A8C5.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).